Somatic mutation profile of tumor specimen TCGA-CC-A8HT-01A (aliquot TCGA-CC-A8HT-01A-11D-A35Z-10) from TCGA case TCGA-CC-A8HT, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,334 days).
Specimen TCGA-CC-A8HT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c35b3cd3-2805-4e51-9285-c44815064886.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A8HT-10A (Blood Derived Normal), aliquot TCGA-CC-A8HT-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c238b08a-9e9b-49c0-b946-f04b234539cd

The open-access MAF lists 226 somatic variants for this specimen: 174 protein-altering or splice-affecting, 49 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 49, Nonsense Mutation 11, Frame Shift Del 7, Splice Site 3, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs121918468, CM043335, CM096577, COSV100692090, COSV61005148; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.1857G>T p.Q619H | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.423); catalogued as COSV52538890, COSV99425202; called by muse, mutect2, varscan2
- AC008676.3 | c.513G>T p.R171S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as COSV100400339; called by muse, mutect2, varscan2
- ACAP2 | c.280C>A p.H94N | Missense Mutation (SNP) | VAF 117/467 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV100461391; called by muse, mutect2, varscan2
- ACP3 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as COSV100313089; called by muse, mutect2, varscan2
- ADAMTS16 | c.1850+2T>C p.X617_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99939900; called by muse, mutect2, varscan2
- ADAMTS6 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101124625; called by muse, mutect2, varscan2
- ADGRA2 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs372154008; called by muse, mutect2, varscan2
- ADM | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs373413227; called by muse, mutect2
- ALB | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV99890632; called by muse, mutect2, varscan2
- ALKAL2 | c.399A>C p.R133S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99681449; called by muse, mutect2, varscan2
- AMER2 | c.1659C>A p.D553E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100766119, COSV63439062; called by muse, mutect2, varscan2
- ANGPTL8 | c.545A>G p.H182R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99370847; called by muse, mutect2, varscan2
- ARID2 | c.5001T>A p.C1667* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV100535316, COSV57603395; called by muse, mutect2, varscan2
- BBS2 | c.724A>G p.N242D | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99802046; called by muse, mutect2, varscan2
- BEND3 | c.1655A>G p.D552G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV64680941; called by muse, mutect2, varscan2
- BSN | c.5098C>G p.L1700V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.294); catalogued as COSV99607131; called by muse, mutect2, varscan2
- C1orf127 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV100983388; called by muse, mutect2, varscan2
- C1orf94 | c.1778G>T p.G593V (on ENST00000488417 / NM_001134734.2; = p.G403V on NM_032884.5) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100974645; called by muse, mutect2, varscan2
- C2CD3 | c.5261G>T p.C1754F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1388308285, COSV58089859; called by muse, mutect2, varscan2
- C4orf45 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV101465074; called by muse, mutect2, varscan2
- CACNA1S | c.4105G>A p.A1369T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100754615; called by muse, mutect2, varscan2
- CAMKK2 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100242569; called by muse, mutect2, varscan2
- CCDC178 | c.1688C>A p.A563E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100283148; called by muse, mutect2, varscan2
- CCDC88A | c.1179T>A p.D393E | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV99709717; called by muse, mutect2, varscan2
- CDH7 | c.2050A>T p.R684W | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100541320; called by muse, mutect2, varscan2
- CDHR2 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.408); catalogued as COSV99990957; called by muse, mutect2, varscan2
- CELF3 | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as COSV99309995; called by muse, mutect2, varscan2
- CEP83 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100352615; called by muse, mutect2, varscan2
- CHD6 | c.4762A>G p.T1588A | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100950515; called by muse, mutect2, varscan2
- CTPS2 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 117/235 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV100826700; called by muse, mutect2, varscan2
- CUBN | c.2576C>T p.T859I | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.15); catalogued as COSV100912015; called by muse, mutect2, varscan2
- DLD | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs201652869; called by muse, mutect2, varscan2
- DOCK2 | c.4625G>T p.G1542V | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99910085; called by muse, mutect2, varscan2
- DOP1A | c.3229G>T p.D1077Y | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99380820; called by muse, mutect2, varscan2
- EEA1 | c.1631A>G p.K544R | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100466979; called by muse, mutect2, varscan2
- EFCAB6 | c.2983G>C p.E995Q | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV99412337, COSV99414448; called by muse, mutect2, varscan2
- EFCAB6 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 25/83 reads (30%) | catalogued as rs372200947; called by muse, mutect2, varscan2
- EGLN2 | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV58280058; called by muse, mutect2
- EPHA4 | c.1880T>C p.I627T | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773524736, COSV99915431; called by muse, mutect2, varscan2
- EPHA6 | c.2372G>C p.G791A (on ENST00000389672 / NM_001080448.3; = p.G183A on NM_173655.4) | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101060748; called by muse, mutect2, varscan2
- EPHB6 | c.1910G>A p.S637N | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV63890606; called by muse, mutect2, varscan2
- ERICH3 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV58615541; called by muse, mutect2
- ESPL1 | c.5321G>A p.R1774Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.464); catalogued as rs542853803, COSV99228851; called by muse, mutect2, varscan2
- EVI5L | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1348950414, COSV99562841; called by muse, mutect2, varscan2
- FAM3C | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV100739780; called by muse, mutect2, varscan2
- FAT1 | c.2126T>C p.V709A | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV101498908; called by muse, mutect2, varscan2
- FAT4 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV101271811, COSV67893013; called by muse, mutect2, varscan2
- FBH1 | c.51G>C p.L17F (on ENST00000362091 / NM_178150.3; = p.L68F on NM_032807.4) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV100758583; called by muse, mutect2, varscan2
- FBN2 | c.3308G>T p.G1103V | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV99324644; called by muse, mutect2, varscan2
- FEZF2 | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.116); catalogued as COSV99334477; called by muse, mutect2, varscan2
- FREM2 | c.7762G>T p.E2588* | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | catalogued as COSV99746630; called by muse, mutect2, varscan2
- FRMD6 | c.656A>G p.Y219C (on ENST00000344768 / NM_001267046.2; = p.Y211C on NM_152330.4) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100655536; called by muse, mutect2
- GABRA1 | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50098576, COSV99195690; called by muse, mutect2, varscan2
- GABRA6 | c.655A>T p.T219S | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.781); catalogued as COSV99194048; called by muse, mutect2, varscan2
- GGNBP2 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1331050485; called by muse, mutect2, varscan2
- GPR155 | c.2017C>T p.L673F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV99789651; called by muse, mutect2, varscan2
- GRSF1 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0.191); catalogued as COSV99635486; called by muse, mutect2, varscan2
- H2AW | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100797238; called by muse, mutect2, varscan2
- HDAC9 | c.2155G>T p.G719C | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101286044; called by muse, mutect2, varscan2
- HIP1 | c.2155G>T p.D719Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs782195793, COSV100416876, COSV61189791; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.490G>T p.D164Y (on ENST00000354667 / NM_031243.3; = p.D152Y on NM_002137.4) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100522837, COSV61160465; called by muse, mutect2, varscan2
- HTRA3 | c.872T>A p.M291K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100246177; called by muse, mutect2, varscan2
- IGDCC3 | c.1211A>G p.N404S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100030615; called by muse, mutect2, varscan2
- INPP5E | c.282G>T p.R94S | Missense Mutation (SNP) | VAF 95/366 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99255975; called by muse, mutect2, varscan2
- ITGB8 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV99750467; called by muse, mutect2, varscan2
- IVL | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100908092; called by muse, mutect2, varscan2
- KANK1 | c.798G>T p.Q266H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100619409; called by muse, mutect2, varscan2
- KANK1 | c.2532C>A p.N844K | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV100619411; called by muse, mutect2, varscan2
- KBTBD6 | c.1206G>T p.R402S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV101068688, COSV65271998; called by muse, mutect2, varscan2
- KDM2B | c.1503G>C p.E501D | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100997141; called by muse, mutect2, varscan2
- KIT | c.2294A>G p.D765G | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1060502545, COSV99853092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRTAP10-12 | c.186C>A p.C62* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100551737; called by muse, mutect2, varscan2
- LRP1 | c.5810A>G p.Y1937C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99674247; called by mutect2, varscan2
- LRRC14 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1457231623, COSV52882225; called by muse, mutect2, varscan2
- LRRTM4 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV101297412; called by muse, mutect2, varscan2
- MAP2K7 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV101208966, COSV67608087; called by muse, mutect2, varscan2
- MAP3K9 | c.1063T>G p.L355V | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101173442; called by muse, mutect2, varscan2
- MAPK1 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53190446; called by muse, mutect2, varscan2
- MCHR1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs199697488, COSV50760980; called by muse, mutect2, varscan2
- METRNL | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as rs1355436892, COSV100193574; called by muse, mutect2, varscan2
- MFSD2A | c.682G>T p.D228Y (on ENST00000372809 / NM_001136493.3; = p.D215Y on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100861601; called by muse, mutect2, varscan2
- MUC16 | c.29423C>T p.P9808L | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV101197948; called by muse, mutect2, varscan2
- MUC17 | c.9284T>G p.M3095R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.599); catalogued as COSV100071427; called by muse, mutect2, varscan2
- MYH13 | c.2825C>A p.A942D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99352110; called by muse, mutect2, varscan2
- NCK1 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as COSV56638110; called by muse, mutect2, varscan2
- NCR3 | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs752238331, COSV53000733; called by muse, mutect2, varscan2
- NDUFS2 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs863224104, COSV100917318; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEK4 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99237110; called by muse, mutect2, varscan2
- NLGN3 | c.694G>C p.V232L (on ENST00000358741 / NM_181303.2; = p.V212L on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100704531, COSV62444399; called by muse, mutect2, varscan2
- NOL4 | c.265-1G>T p.X89_splice | Splice Site (SNP) | VAF 20/81 reads (25%) | catalogued as COSV99304862, COSV99307422; called by muse, mutect2, varscan2
- NPL | c.788T>A p.V263E | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99277225; called by muse, mutect2, varscan2
- OR51A7 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV63788320; called by muse, mutect2, varscan2
- OR5K2 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV101415945; called by muse, mutect2, varscan2
- OR8A1 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52510437, COSV99420270; called by muse, mutect2, varscan2
- PCLO | c.14601G>T p.M4867I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV100427054; called by muse, mutect2
- PDK4 | c.865A>T p.I289F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99138725; called by muse, mutect2, varscan2
- PER1 | c.438G>C p.K146N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100424219; called by muse, mutect2, varscan2
- PFKFB1 | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 63/105 reads (60%) | PolyPhen benign (0.397); catalogued as COSV100895590; called by muse, mutect2, varscan2
- PFKFB1 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 61/103 reads (59%) | PolyPhen benign (0.033); catalogued as COSV100895592; called by muse, mutect2, varscan2
- PHF20 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100179853; called by muse, mutect2, varscan2
- PLD5 | c.1349A>T p.Y450F (on ENST00000442594; = p.Y388F on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV100138683, COSV59134055; called by muse, mutect2, varscan2
- PLEKHA6 | c.2305G>T p.G769C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99691472; called by muse, mutect2, varscan2
- PLEKHM1 | c.3022G>T p.D1008Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101378658; called by muse, mutect2, varscan2
- PMP2 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56267012, COSV99808089; called by muse, mutect2, varscan2
- POC1A | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99623890; called by muse, mutect2, varscan2
- PPM1H | c.1247T>A p.V416E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99955117; called by muse, mutect2, varscan2
- PREX2 | c.2583G>T p.E861D | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99904711; called by muse, mutect2, varscan2
- PRMT8 | c.1101+1G>A p.X367_splice | Splice Site (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99713110; called by muse, mutect2, varscan2
- PSKH1 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs374100286, COSV99344436; called by muse, mutect2, varscan2
- PTGER3 | c.928A>T p.T310S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.609); catalogued as COSV100138112; called by muse, mutect2, varscan2
- PTPRM | c.2577T>A p.H859Q | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.852); catalogued as COSV100154596; called by muse, mutect2, varscan2
- PTPRM | c.3089A>T p.E1030V | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs551645103, COSV100154600; called by muse, mutect2, varscan2
- PZP | c.1016T>A p.I339N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99735848; called by muse, mutect2, varscan2
- PZP | c.133A>T p.K45* | Nonsense Mutation (SNP) | VAF 32/126 reads (25%) | catalogued as COSV99735855; called by muse, mutect2, varscan2
- RAD54B | c.2611C>G p.L871V | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1015013570, COSV100279332; called by muse, mutect2, varscan2
- RAVER1 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99348855; called by muse, mutect2, varscan2
- RGS22 | c.2883G>C p.R961S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100692963, COSV62659779; called by muse, mutect2, varscan2
- RPS6KA4 | c.2225G>T p.R742L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs111697527, COSV53706695, COSV99589749; called by muse, mutect2
- SAMSN1 | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99580579; called by muse, mutect2, varscan2
- SCNN1D | c.733C>G p.P245A (on ENST00000338555; = p.P409A on NM_001130413.4) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV100329435; called by muse, mutect2, varscan2
- SDK1 | c.2540C>G p.A847G | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV101268720; called by muse, mutect2, varscan2
- SEMA3D | c.1841T>C p.I614T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV52398379; called by muse, mutect2, varscan2
- SETD5 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100200090; called by muse, mutect2, varscan2
- SH3TC1 | c.2368A>G p.T790A | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1227501885, COSV99794353; called by muse, mutect2, varscan2
- SHANK1 | c.2644C>T p.P882S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV99519800; called by muse, mutect2, varscan2
- SHE | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.998); catalogued as rs1178481795, COSV100495837; called by muse, mutect2, varscan2
- SLC25A45 | c.422del p.P141Hfs*30 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | catalogued as COSV53683559; called by mutect2, pindel, varscan2
- SLC39A10 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 85/359 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); catalogued as COSV100660460; called by muse, mutect2, varscan2
- SLC39A10 | c.577A>T p.T193S | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100660462; called by muse, mutect2, varscan2
- SLC4A10 | c.1731G>T p.K577N (on ENST00000446997 / NM_001354461.2; = p.K547N on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs534495211, COSV55764267, COSV99764098; called by muse, mutect2, varscan2
- SLC6A7 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100045926; called by muse, mutect2, varscan2
- SLC7A14 | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.994); catalogued as COSV51579054; called by muse, mutect2, varscan2
- SPIDR | c.1157A>T p.E386V | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV99854129; called by muse, mutect2, varscan2
- SRRM4 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV99937642; called by muse, mutect2, varscan2
- SRSF6 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54828666; called by muse, mutect2, varscan2
- STK35 | c.439A>C p.S147R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV99852571; called by muse, mutect2, varscan2
- STN1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99830094; called by muse, mutect2, varscan2
- SVIL | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100880855, COSV100881289; called by muse, mutect2
- TECR | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.432); catalogued as COSV99294999; called by muse, mutect2, varscan2
- TIMD4 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as COSV99192478; called by muse, mutect2, varscan2
- TMEM19 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99876789; called by muse, mutect2, varscan2
- TOX | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100812560, COSV63844147; called by muse, mutect2, varscan2
- TRIM51 | c.563C>A p.A188E | Missense Mutation (SNP) | VAF 106/354 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.094); catalogued as COSV99792104; called by muse, mutect2, varscan2
- TRO | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 55/101 reads (54%) | catalogued as COSV99435691; called by muse, mutect2, varscan2
- TRPS1 | c.2503G>A p.A835T (on ENST00000220888 / NM_001330599.2; = p.A848T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.679); catalogued as rs377704400; called by muse, mutect2, varscan2
- TSC2 | c.5025del p.L1676Wfs*150 | Frame Shift Del (DEL) | VAF 39/103 reads (38%) | catalogued as rs137854382, CD982989, COSV51927823; ClinVar: not provided; called by mutect2, pindel, varscan2
- TTN | c.61078C>A p.P20360T (on ENST00000591111; = p.P12936T on NM_003319.4) | Missense Mutation (SNP) | VAF 28/143 reads (20%) | PolyPhen benign (0.124); catalogued as COSV100592604; called by muse, mutect2, varscan2
- ULK1 | c.3010G>A p.V1004I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.684); catalogued as rs202232188, COSV100416457; called by muse, mutect2, varscan2
- USH2A | c.4054T>A p.W1352R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100228425, COSV100232788; called by muse, mutect2, varscan2
- VPS39 | c.2602C>T p.P868S (on ENST00000348544 / NM_001301138.2; = p.P857S on NM_015289.5) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99300304; called by muse, mutect2, varscan2
- VPS51 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99660822; called by muse, mutect2, varscan2
- XCL1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 27/340 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs765177999, COSV63191812; called by muse, mutect2
- XCL2 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs780406644, COSV63193912; called by muse, mutect2, varscan2
- ZDBF2 | c.719C>G p.P240R | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.326); catalogued as COSV100984315; called by muse, mutect2, varscan2
- ZNF281 | c.984G>T p.Q328H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99663973; called by muse, mutect2, varscan2
- ZNF322 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.108); catalogued as COSV101338450; called by mutect2, varscan2
- ZNF442 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV54422752; called by muse, mutect2, varscan2
- ZNF521 | c.2527G>T p.G843* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as COSV64128617; called by muse, mutect2, varscan2
- ZNF93 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100652114; called by muse, mutect2, varscan2
- ZRANB1 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV100669039; called by muse, mutect2
- ZRSR2 | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 97/198 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100314915; called by muse, mutect2, varscan2
- FCGBP | c.2413G>T p.G805C | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GGNBP2 | c.1989A>T p.E663D | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV7-46 | c.227A>T p.H76L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- KIR3DL2 | c.459C>A p.F153L | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PER1 | c.2962_2998del p.Q988Lfs*122 | Frame Shift Del (DEL) | VAF 30/120 reads (25%) | called by mutect2, pindel
- PER1 | c.2195del p.G732Efs*12 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- PHF14 | c.1723del p.A575Lfs*46 | Frame Shift Del (DEL) | VAF 47/253 reads (19%) | called by mutect2, pindel, varscan2
- RBP3 | c.3306A>C p.E1102D | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ST7 | c.276_279del p.F92Lfs*6 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by pindel, varscan2
- ST8SIA5 | c.843_850del p.Y281* | Nonsense Mutation (DEL) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- SYNE1 | c.9538del p.V3180* (on ENST00000367255 / NM_182961.4; = p.V3187* on NM_033071.3) | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- ACACB | c.1455A>G p.P485= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100622253; called by muse, mutect2, varscan2
- AHNAK | c.13767G>A p.K4589= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV99945402; called by muse, mutect2, varscan2
- ALDOB | c.684G>A p.L228= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100878803; called by muse, mutect2, varscan2
- ARSA | c.246G>A p.R82= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV53350744; called by muse, mutect2, varscan2
- BSN | c.4929C>T p.C1643= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1330196798, COSV99607129; called by muse, mutect2, varscan2
- C1orf198 | c.492C>A p.A164= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV100793317; called by muse, mutect2
- C9orf131 | c.2176C>T p.L726= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100397904; called by muse, mutect2, varscan2
- CCN5 | c.627G>A p.G209= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99509156; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.129C>T p.R43= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV99267204; called by muse, mutect2, varscan2
- CNTNAP5 | c.3816C>T p.S1272= | Silent (SNP) | VAF 85/334 reads (25%) | catalogued as rs1345887588, COSV70514316; called by muse, mutect2, varscan2
- COL4A6 | c.189T>C p.P63= | Silent (SNP) | VAF 45/80 reads (56%) | catalogued as COSV100563246; called by muse, mutect2, varscan2
- DNM3 | c.2097C>A p.S699= (on ENST00000355305 / NM_001350206.2; = p.S693= on NM_015569.5) | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV100797748, COSV62455799; called by muse, mutect2, varscan2
- DOP1B | c.2334G>A p.T778= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs756665654, COSV67692835; called by muse, mutect2, varscan2
- EPHA6 | c.2373G>T p.G791= (on ENST00000389672 / NM_001080448.3; = p.G183= on NM_173655.4) | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as COSV101060749; called by muse, mutect2, varscan2
- EPHB6 | c.1071G>C p.R357= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV67421138; called by muse, mutect2, varscan2
- ERICH3 | c.1518G>A p.E506= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs745497573, COSV100443276, COSV58614296; called by muse, mutect2
- FLRT1 | c.39G>A p.T13= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs575714111, COSV99734570; called by muse, mutect2, varscan2
- GPAT2 | c.1639C>T p.L547= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100853209; called by muse, mutect2, varscan2
- GPRIN2 | c.1080G>T p.L360= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100966276; called by muse, mutect2, varscan2
- HIBADH | c.723T>C p.A241= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV99606836; called by muse, mutect2, varscan2
- HIVEP3 | c.2913G>A p.L971= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV99911359; called by muse, mutect2, varscan2
- IGFN1 | c.1875G>A p.L625= (on ENST00000295591 / NM_001367841.1; = p.L3082= on NM_001164586.2) | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV99811012; called by muse, mutect2, varscan2
- IGKV2D-28 | c.105T>G p.P35= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV101494550; called by mutect2, varscan2
- KIAA2026 | c.3378A>G p.P1126= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs780506945, COSV101198827; called by muse, mutect2, varscan2
- LRRC31 | c.522G>A p.E174= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99246268; called by muse, mutect2, varscan2
- MAGI1 | c.2895G>A p.V965= (on ENST00000402939 / NM_001033057.2; = p.V993= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100439185; called by muse, mutect2, varscan2
- MYO15A | c.4435C>T p.L1479= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV99230962; called by muse, mutect2, varscan2
- NFATC1 | c.519G>T p.P173= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99500452; called by muse, mutect2, varscan2
- NLRP12 | c.1626C>T p.T542= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs753966022, COSV100144793; called by muse, mutect2, varscan2
- NUTM2G | c.435G>A p.Q145= | Silent (SNP) | VAF 17/181 reads (9%) | catalogued as rs755759002, COSV100672549; called by muse, mutect2, varscan2
- OBSCN | c.13137C>G p.P4379= | Silent (SNP) | VAF 74/203 reads (36%) | catalogued as COSV99471926; called by muse, mutect2, varscan2
- OR10G9 | c.42C>A p.G14= | Silent (SNP) | VAF 43/196 reads (22%) | catalogued as rs1288286467, COSV100901461, COSV100901810; called by muse, varscan2
- OR7G3 | c.360T>C p.Y120= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV100555592; called by muse, mutect2, varscan2
- PDLIM5 | c.915G>A p.K305= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100523307; called by muse, mutect2, varscan2
- PKHD1L1 | c.888T>C p.D296= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV101005247; called by muse, mutect2, varscan2
- RPTN | c.2139T>G p.T713= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV60167678; called by muse, mutect2, varscan2
- RTL6 | c.123G>T p.R41= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100373715; called by muse, mutect2, varscan2
- SCN5A | c.3646C>T p.L1216= (on ENST00000333535 / NM_198056.3; = p.L1215= on NM_000335.5) | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs1036340226, COSV100346302; called by muse, mutect2, varscan2
- SFMBT2 | c.2205G>A p.E735= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100738359; called by muse, mutect2, varscan2
- SNAI3 | c.417G>T p.L139= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100178760; called by muse, mutect2, varscan2
- TASOR2 | c.5833A>C p.R1945= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100049925; called by muse, mutect2, varscan2
- TBC1D16 | c.1614G>A p.A538= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as rs755415779, COSV100187688; called by muse, mutect2, varscan2
- TTC39C | c.699G>A p.V233= (on ENST00000317571 / NM_001135993.2; = p.V172= on NM_153211.4) | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV100455113, COSV58219801; called by muse, mutect2, varscan2
- TUT1 | c.1359G>T p.V453= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as COSV99544930; called by muse, mutect2, varscan2
- USF3 | c.2184A>G p.Q728= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV100324680; called by muse, mutect2, varscan2
- XIRP2 | c.4779A>G p.T1593= (on ENST00000628543; = p.T1768= on NM_152381.6) | Silent (SNP) | VAF 52/194 reads (27%) | catalogued as rs775529913, COSV99737961; called by muse, mutect2, varscan2
- ZBBX | c.234A>G p.Q78= | Silent (SNP) | VAF 93/344 reads (27%) | catalogued as rs1427515222, COSV100283028; called by muse, mutect2, varscan2
- ZGRF1 | c.1002G>A p.Q334= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV100005296; called by muse, mutect2, varscan2
- ZNF253 | c.1311A>T p.S437= | Silent (SNP) | VAF 44/198 reads (22%) | catalogued as COSV100849437; called by muse, mutect2, varscan2
- LINC00518 | n.984C>A | RNA (SNP) | VAF 28/105 reads (27%) | catalogued as rs1478925846; called by muse, mutect2, varscan2
- OBSCN | c.18662-2966A>T | Intron (SNP) | VAF 23/123 reads (19%) | catalogued as COSV99471934; called by muse, mutect2, varscan2
- SPATA8 | n.281C>A | RNA (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100138874; called by muse, mutect2, varscan2
